TARGET case TARGET-40-0A4I0S — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/d1da3ccf-bfbb-4fc1-9c68-355194ceac9b

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 25.0 years (9,114 days); Year of diagnosis: 2006; Days to last follow up: 603 days (1.7 years).

Biospecimens (2 samples)
- Sample TARGET-40-0A4I0S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I0S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
